Gene-level copy-number profile of tumor specimen ALCH-B0BL-TTP1-A from ALCHEMIST case ALCH-B0BL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.2 years (21,637 days).
Specimen ALCH-B0BL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8edfdaae-2b8b-4933-9607-ec156ca18106.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B0BL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/97a25cd8-33b4-4754-868e-f3e53912a305

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 96; copy number 1: 14,291; copy number 2: 38,449; copy number 3: 4,286; copy number 4: 693; copy number 5: 236; copy number 6: 92; copy number 7: 3; copy number 8: 29; copy number 9: 76; copy number 10: 107; copy number 14: 39; copy number 19: 3.

Homozygous deletions (total copy number 0; autosomes only): 92 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:53,064,283–53,130,453, 2 genes (within-gene range 0–1): SERBP1P3, RFT1.
- chr6:61,240,898–61,241,311, 1 gene: AL356131.1.
- chr8:43,539,137–43,544,057, 3 genes: AC134698.5, CYP4F44P, AC134698.2.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–1): CRB2.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:134,378,504–134,412,242, 1 gene: B3GAT1.
- chr12:33,923,374–33,923,480, 1 gene: RNU6-472P.
- chr12:34,249,481–37,576,384, 2 genes: AK6P1, ZNF970P.
- chr16:32,185,624–32,213,503, 5 genes (within-gene range 0–2): AC133485.6, AC133485.5, AC133485.4, ABHD17AP8, AC133485.1.
- chr16:32,289,547–32,380,049, 3 genes: AC133548.2, AC133548.1, ACTR3BP3.
- chr16:32,600,299–32,788,944, 15 genes: AC137800.1, AC133569.1, AC138907.7, AC138907.5, AC138907.1, TP53TG3, AC138907.3, AC138907.6, ABHD17AP7, AC138907.2, AC138907.4, HERC2P5, AC138907.8, AC138907.9, AC138907.10.
- chr16:32,845,964–32,873,128, 2 genes: AC142086.2, BCAP31P2.
- chr16:33,533,816–33,570,935, 4 genes: AC136944.1, AC136944.2, AC136944.4, AC136944.3.
- chr16:33,802,764–33,803,217, 1 gene: IGHV3OR16-12.
- chr16:33,907,419–34,163,110, 18 genes: ARHGAP23P1, IGHV3OR16-7, AC140658.4, IGHV3OR16-16, AC140658.1, AC140658.5, AC133561.1, BCAP31P1, AC133561.2, AC133561.4, AC133561.3, AC136932.1, DUX4L45, PCMTD1P2, DUX4L46, DUX4L47, LINC00273, RNA5-8SP2.
- chr16:35,040,164–35,085,060, 2 genes (within-gene range 0–4): CCNYL3, CLUHP11.
- chr16:89,720,400–90,222,851, 24 genes (within-gene range 0–1): ZNF276, FANCA, SPIRE2, TCF25, AC092143.3, MC1R, AC092143.1, AC092143.2, TUBB3, DEF8, CENPBD1, AFG3L1P, DBNDD1, GAS8, GAS8-AS1, URAHP, PRDM7, TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:18,476,737–18,494,945, 1 gene: LGALS9C.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 585 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:48,660,125–57,837,046, 196 genes, copy number 6–10 (broad region; genes not listed).
- chr7:63,011,463–69,597,493, 213 genes, copy number 5–10 (broad region; genes not listed).
- chr12:57,591,174–58,813,060, 42 genes, copy number 7–14: PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2, AC083805.1, AC083805.3, ATP23, GIHCG, AC084033.1, RN7SKP65, AC084033.2, LINC02403, AC090643.1, AC090643.2, RPL21P103, AC025578.1, AC020637.1, LINC02388.
- chr16:35,021,749–35,024,250, 3 genes, copy number 19: AC135776.1, AC135776.2, AC135776.3.
- chr19:685,546–1,395,589, 51 genes, copy number 5 (within-gene range 2–5): PRSS57, RPS2P52, PALM, MISP, AC006273.1, LINC01836, PTBP1, MIR4745, PLPPR3, MIR3187, AZU1, PRTN3, ELANE, CFD, MED16, RNU6-9, R3HDM4, KISS1R, ARID3A, AC005379.1, AC005391.1, WDR18, AC004528.1, GRIN3B, TMEM259, AC004528.2, RNU6-2, CNN2, AC011558.1, ABCA7, ARHGAP45, POLR2E, GPX4, SBNO2, STK11, HMGB2P1, CBARP, AC004221.1, ATP5F1D, MIDN, CIRBP, CIRBP-AS1, FAM174C, EFNA2, RPS15P9, AC005330.1, PWWP3A, AC004623.1, AC005329.2, NDUFS7, AC005329.3.
- chr20:62,596,732–63,832,038, 72 genes, copy number 5 (broad region; genes not listed).
- chr20:63,895,126–63,936,031, 7 genes, copy number 6: DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5.
- chr21:43,414,483–43,427,131, 1 gene, copy number 5: SIK1.

Autosomal genes at a single copy (total copy number 1): 14,291. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
